Somatic mutation profile of tumor specimen TCGA-61-2012-01A (aliquot TCGA-61-2012-01A-01W-0722-08) from TCGA case TCGA-61-2012, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIC; Tumor grade: G2; Age at diagnosis: 81.7 years (29,830 days).
Specimen TCGA-61-2012-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50faed83-43e7-4e3f-bed4-8e07fd77fa61.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-2012-11A (Solid Tissue Normal), aliquot TCGA-61-2012-11A-01W-0722-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07c95e9c-a5c1-4a14-8c2d-4c42c491d68c

The open-access MAF lists 141 somatic variants for this specimen: 107 protein-altering or splice-affecting, 32 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 94, Silent 32, Nonsense Mutation 6, Frame Shift Del 2, Splice Site 2, RNA 2, Splice Region 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TRNT1 | c.1252del p.S418Vfs*11 | Frame Shift Del (DEL) | VAF 16/94 reads (17%) | catalogued as rs876661298, CM1411168, COSV51642664; ClinVar: likely pathogenic / pathogenic; called by pindel, varscan2
- ABCA4 | c.4489A>T p.T1497S | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.14); PolyPhen benign (0.047); catalogued as COSV64673276; called by muse, varscan2
- ACSL3 | c.1973T>C p.V658A | Missense Mutation (SNP) | VAF 82/457 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as COSV62481986; called by muse, mutect2, varscan2
- ADAMTS13 | c.1669C>T p.P557S | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV63021091; called by mutect2, varscan2
- AHNAK | c.17135T>C p.I5712T | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57212329; called by muse, mutect2, varscan2
- ARHGAP21 | c.525+2T>A p.X175_splice | Splice Site (SNP) | VAF 34/196 reads (17%) | catalogued as COSV57605428; called by muse, varscan2
- ARL4C | c.563A>C p.Q188P | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as COSV60213835; called by muse, mutect2, varscan2
- ARMCX3 | c.287C>G p.A96G | Missense Mutation (SNP) | VAF 59/212 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.262); catalogued as COSV57870354; called by muse, mutect2, varscan2
- ATP11B | c.2536G>T p.A846S | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371088881; called by muse, mutect2, varscan2
- BCL6 | c.878A>T p.Y293F | Missense Mutation (SNP) | VAF 45/219 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as COSV51651782; called by muse, mutect2, varscan2
- BTK | c.584A>T p.D195V | Missense Mutation (SNP) | VAF 60/273 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.029); catalogued as COSV100437992; called by muse, mutect2, varscan2
- C4BPA | c.1601A>T p.E534V | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV65536310; called by muse, mutect2, varscan2
- CADPS | c.1040T>A p.V347D | Missense Mutation (SNP) | VAF 63/224 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99341387; called by muse, mutect2, varscan2
- CBLL1 | c.835C>T p.Q279* | Nonsense Mutation (SNP) | VAF 33/165 reads (20%) | catalogued as COSV56028828; called by muse, mutect2, varscan2
- CCDC141 | c.3524A>C p.E1175A | Missense Mutation (SNP) | VAF 37/297 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV55372937; called by muse, mutect2, varscan2
- CDH9 | c.860T>G p.L287R | Missense Mutation (SNP) | VAF 20/675 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1476371730, COSV99161100; called by muse, mutect2
- COL18A1 | c.1772T>C p.L591P (on ENST00000359759 / NM_130444.3; = p.L356P on NM_030582.4) | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62701108; called by muse, mutect2, varscan2
- CORO2B | c.1005C>G p.C335W | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55952646; called by mutect2, varscan2
- CTTNBP2NL | c.362G>T p.R121L | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV54744312; called by muse, mutect2, varscan2
- CYP11B1 | c.325C>A p.H109N | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.068); catalogued as COSV52826756; called by muse, mutect2, varscan2
- DENND2A | c.1513C>T p.Q505* | Nonsense Mutation (SNP) | VAF 200/655 reads (31%) | catalogued as COSV99327138; called by muse, mutect2, varscan2
- DIO3 | c.796A>G p.S266G | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV63773519; called by muse, mutect2, varscan2
- EHD4 | c.1514C>T p.A505V | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.322); catalogued as rs763781516, COSV55004616; called by muse, mutect2, varscan2
- ERO1A | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.091); catalogued as COSV101193692; called by muse, mutect2, varscan2
- EXTL1 | c.88C>T p.L30F | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.77); catalogued as rs1206115885, COSV65337476; called by muse, mutect2, varscan2
- FBN1 | c.5314G>A p.E1772K | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as CM077260, COSV100354226, COSV100356561; called by muse, mutect2
- FRAS1 | c.7171G>A p.G2391S | Missense Mutation (SNP) | VAF 40/265 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.207); catalogued as rs990501513, COSV53604893; called by muse, mutect2, varscan2
- FRMPD1 | c.1075A>G p.S359G | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.477); catalogued as COSV66700228; called by muse, mutect2, varscan2
- GALR1 | c.800A>G p.H267R | Missense Mutation (SNP) | VAF 66/653 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.116); catalogued as rs980582340, COSV100232124; called by muse, varscan2
- GATAD2B | c.1266G>T p.Q422H | Missense Mutation (SNP) | VAF 16/312 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100898054; called by muse, mutect2
- GBP6 | c.293C>A p.T98N | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65011392, COSV65012744; called by muse, mutect2, varscan2
- GDF3 | c.4C>A p.L2I | Missense Mutation (SNP) | VAF 55/105 reads (52%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV61712394; called by muse, mutect2, varscan2
- GON4L | c.2351C>T p.A784V | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as rs779140286, COSV55192969; called by muse, mutect2, varscan2
- GPR155 | c.865G>T p.V289L | Missense Mutation (SNP) | VAF 15/189 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV99790283; called by muse, mutect2
- GSDMB | c.169A>G p.T57A | Missense Mutation (SNP) | VAF 30/404 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as rs1449249354, COSV100401603; called by muse, mutect2
- HPS3 | c.2569G>C p.E857Q | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV99937698; called by muse, mutect2
- ICE1 | c.5078C>G p.P1693R | Missense Mutation (SNP) | VAF 82/836 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56823659; called by muse, mutect2
- ICMT | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV59474594; called by muse, mutect2, varscan2
- IFNA13 | c.37G>T p.V13L | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs750600628, COSV71924488; called by muse, mutect2, varscan2
- IGHE | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 40/343 reads (12%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.636); catalogued as rs1244688726; called by muse, mutect2, varscan2
- IGSF3 | c.3161G>C p.R1054P (on ENST00000369486 / NM_001007237.3; = p.R1074P on NM_001542.4) | Missense Mutation (SNP) | VAF 67/121 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV59590184, COSV59595226; called by muse, mutect2, varscan2
- IGSF3 | c.2818G>A p.G940R (on ENST00000369486 / NM_001007237.3; = p.G960R on NM_001542.4) | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as rs1285360050, COSV100605173; called by muse, mutect2, varscan2
- KIAA1549L | c.3299G>A p.R1100Q (on ENST00000321505; = p.R1397Q on NM_012194.3) | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746216491, COSV55772941; called by muse, mutect2, varscan2
- LAMA2 | c.4097G>T p.R1366L | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as rs573563174, COSV70346076; called by muse, mutect2, varscan2
- LAMA5 | c.5200G>A p.D1734N | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99442770; called by muse, mutect2
- LRCH1 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 22/279 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.917); catalogued as COSV100244140; called by muse, mutect2
- LRFN5 | c.2072C>T p.T691M | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV53254589, COSV53260302; called by muse, mutect2, varscan2
- LRRK2 | c.3575T>C p.I1192T | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV54152166; called by muse, mutect2, varscan2
- MTTP | c.1361A>G p.K454R | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.191); catalogued as COSV55505615; called by muse, mutect2, varscan2
- MYH8 | c.4165C>A p.L1389M | Missense Mutation (SNP) | VAF 28/559 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101238952; called by muse, mutect2
- NIPBL | c.458G>A p.S153N | Missense Mutation (SNP) | VAF 22/484 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.227); catalogued as COSV99243101; called by muse, mutect2
- NOTCH1 | c.6979C>T p.R2327W | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.794); catalogued as rs751007903, COSV53046255; ClinVar: uncertain significance / not provided; called by muse, mutect2
- NUDCD1 | c.847A>T p.T283S | Missense Mutation (SNP) | VAF 31/308 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.417); catalogued as COSV53455707, COSV53456657; called by muse, mutect2, varscan2
- ONECUT2 | c.1312C>T p.R438C | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1449358331, COSV72153018; called by muse, mutect2, varscan2
- OR1E1 | c.851T>A p.M284K | Missense Mutation (SNP) | VAF 92/1906 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100492062; called by muse, mutect2
- OR4C13 | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 104/334 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as COSV101634152, COSV73648737; called by muse, varscan2
- PARP4 | c.3470C>G p.S1157C | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1274539404, COSV101131377, COSV101132135; called by muse, varscan2
- PDZRN3 | c.2804A>G p.K935R | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.991); catalogued as COSV55198190; called by muse, mutect2, varscan2
- PIGR | c.1731G>T p.K577N | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV62903859; called by muse, mutect2, varscan2
- PKP2 | c.637C>T p.H213Y | Missense Mutation (SNP) | VAF 24/212 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV50730183; called by muse, mutect2, varscan2
- PLPPR4 | c.858T>A p.F286L | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.868); catalogued as COSV64565619; called by muse, mutect2, varscan2
- PLXNA4 | c.5330C>T p.T1777I | Missense Mutation (SNP) | VAF 35/247 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV58122621; called by muse, mutect2, varscan2
- POLG | c.2473G>A p.V825M | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1344797678, COSV51521359; called by muse, mutect2, varscan2
- POLR1A | c.4578G>A p.Q1526= | Splice Region (SNP) | VAF 77/308 reads (25%) | catalogued as COSV55692464; called by muse, mutect2, varscan2
- POLR3E | c.715G>C p.V239L | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.07); catalogued as rs754906748, COSV55400302, COSV55403378; called by muse, mutect2, varscan2
- RASL12 | c.182A>T p.E61V | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.963); catalogued as COSV99585242; called by muse, mutect2, varscan2
- RASL12 | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 15/91 reads (16%) | catalogued as COSV99585206, COSV99585243; called by muse, mutect2, varscan2
- RGP1 | c.716T>C p.V239A | Missense Mutation (SNP) | VAF 74/260 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as rs1399498965, COSV65239460; called by muse, mutect2, varscan2
- RHBDL3 | c.810G>A p.M270I | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.985); catalogued as COSV52185912; called by muse, mutect2, varscan2
- RYK | c.1036C>T p.R346C (on ENST00000620660 / NM_001005861.2; = p.R343C on NM_002958.4) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.274); catalogued as rs752906721, COSV56061959; called by mutect2, varscan2
- RYR3 | c.6120G>T p.M2040I | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.591); catalogued as COSV66787100; called by muse, varscan2
- SCN1A | c.5753C>G p.S1918C (on ENST00000303395 / NM_001202435.3; = p.S1907C on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 174/696 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.993); catalogued as COSV57668939; called by muse, mutect2, varscan2
- SCYL2 | c.1514G>A p.R505H | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs199548769, COSV62568607, COSV62569221; called by muse, mutect2, varscan2
- SERPINA9 | c.1167C>G p.F389L | Missense Mutation (SNP) | VAF 19/566 reads (3%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.651); catalogued as COSV100098925; called by muse, mutect2
- SERPINB4 | c.155A>C p.Q52P | Missense Mutation (SNP) | VAF 108/697 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV61984842; called by muse, mutect2, varscan2
- SETD7 | c.1026dup p.G343Rfs*6 | Frame Shift Ins (INS) | VAF 11/95 reads (12%) | catalogued as rs35259575; called by mutect2, varscan2
- SGK1 | c.1198A>G p.K400E | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV52807897; called by muse, mutect2, varscan2
- SHMT2 | c.1075C>T p.R359W | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs913349362, COSV61073867; called by muse, mutect2, varscan2
- SHOC2 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.788); catalogued as COSV54621629; called by muse, varscan2
- SLC45A2 | c.1024A>T p.M342L | Missense Mutation (SNP) | VAF 38/422 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as rs143509333, COSV56871492; called by muse, mutect2
- SLC4A3 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.754); catalogued as COSV56093412; called by muse, mutect2, varscan2
- SLC4A7 | c.2648C>A p.P883H | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99840201; called by muse, mutect2
- SLC4A7 | c.2432G>C p.G811A | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55396968; called by muse, mutect2, varscan2
- SLFN13 | c.1102C>T p.Q368* | Nonsense Mutation (SNP) | VAF 27/75 reads (36%) | catalogued as COSV53193357; called by muse, mutect2, varscan2
- SPTAN1 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV63986866; called by muse, mutect2, varscan2
- STX8 | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 24/504 reads (5%) | catalogued as COSV100111537, COSV60494400; called by muse, mutect2
- TBX3 | c.79G>T p.D27Y | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV57471199; called by muse, mutect2, varscan2
- TKTL1 | c.128G>A p.S43N | Missense Mutation (SNP) | VAF 34/250 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs782018424, COSV54212748; called by muse, mutect2, varscan2
- TMTC2 | c.1842G>T p.K614N | Missense Mutation (SNP) | VAF 66/623 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as COSV58267598; called by muse, mutect2, varscan2
- TOX2 | c.89C>A p.A30E | Missense Mutation (SNP) | VAF 65/140 reads (46%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.021); catalogued as COSV57885857; called by muse, mutect2, varscan2
- TSHZ2 | c.2661G>T p.K887N | Missense Mutation (SNP) | VAF 34/321 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61588544; called by muse, mutect2
- TTLL7 | c.861T>G p.D287E | Missense Mutation (SNP) | VAF 16/473 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99553406; called by muse, mutect2
- TTN | c.57625G>A p.A19209T (on ENST00000591111; = p.A11785T on NM_003319.4) | Missense Mutation (SNP) | VAF 40/258 reads (16%) | PolyPhen possibly damaging (0.558); catalogued as COSV60027982; called by muse, mutect2, varscan2
- USP33 | c.1982C>G p.S661* | Nonsense Mutation (SNP) | VAF 15/339 reads (4%) | catalogued as COSV100657271; called by muse, mutect2
- WDR17 | c.3084-1G>T p.X1028_splice | Splice Site (SNP) | VAF 17/69 reads (25%) | catalogued as COSV54573275; called by muse, varscan2
- XIRP2 | c.7200C>A p.S2400R (on ENST00000628543; = p.S2575R on NM_152381.6) | Missense Mutation (SNP) | VAF 30/280 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.118); catalogued as COSV99748403; called by muse, mutect2, varscan2
- ZBTB24 | c.1249G>T p.D417Y | Missense Mutation (SNP) | VAF 58/248 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV57781951; called by muse, mutect2, varscan2
- ZBTB38 | c.1502A>C p.E501A | Missense Mutation (SNP) | VAF 52/353 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100376048; called by muse, mutect2, varscan2
- ZBTB41 | c.503T>G p.I168R | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.42); catalogued as COSV66359106; called by muse, mutect2, varscan2
- ZFP64 | c.1025C>A p.P342H | Missense Mutation (SNP) | VAF 62/286 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV53798613; called by muse, mutect2, varscan2
- ZNF208 | c.3396G>T p.K1132N | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV68104698, COSV68108511; called by muse, mutect2, varscan2
- ZNF527 | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 79/805 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as COSV62230384; called by muse, mutect2
- ZNF589 | c.1019G>T p.G340V | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as rs768750112, COSV61220357; called by muse, mutect2, varscan2
- ALDH6A1 | c.929_937del p.F310_A313delinsS | In Frame Del (DEL) | VAF 12/91 reads (13%) | called by mutect2, pindel, varscan2
- NPR1 | c.2286del p.F763Sfs*37 | Frame Shift Del (DEL) | VAF 20/191 reads (10%) | called by mutect2*, pindel, varscan2*
- PGM5 | c.1025C>G p.T342S | Missense Mutation (SNP) | VAF 36/584 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.094); called by muse, mutect2
- TRAV16 | c.252A>C p.K84N | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- AKAP9 | c.8694G>A p.V2898= (on ENST00000359028; = p.V2874= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/121 reads (23%) | catalogued as COSV62344763; called by muse, mutect2, varscan2
- AMIGO1 | c.795G>A p.L265= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV63990370; called by muse, mutect2, varscan2
- AMPD2 | c.447G>A p.G149= | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as COSV99858197; called by muse, mutect2
- CARD14 | c.1758C>T p.I586= | Silent (SNP) | VAF 42/61 reads (69%) | catalogued as rs143677083; ClinVar: likely benign; called by muse, mutect2, varscan2
- CEP78 | c.1839C>T p.L613= (on ENST00000424347 / NM_001349840.2; = p.L614= on NM_032171.3) | Silent (SNP) | VAF 25/92 reads (27%) | catalogued as rs1271005113, COSV52847107; called by muse, varscan2
- COL20A1 | c.147G>A p.S49= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs746409025, COSV58911875; called by muse, mutect2, varscan2
- CYFIP2 | c.1203C>T p.S401= | Silent (SNP) | VAF 27/239 reads (11%) | catalogued as COSV100557923; called by muse, mutect2
- FBN1 | c.5313G>A p.R1771= | Silent (SNP) | VAF 20/250 reads (8%) | catalogued as COSV100356563; called by muse, mutect2
- GALNT6 | c.1143G>C p.G381= | Silent (SNP) | VAF 24/182 reads (13%) | catalogued as COSV100695703, COSV62543578; called by muse, mutect2, varscan2
- IL36B | c.291G>A p.K97= | Silent (SNP) | VAF 43/358 reads (12%) | catalogued as rs1474254799, COSV52086185; called by muse, mutect2, varscan2
- IMPG1 | c.744G>A p.K248= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as COSV100885796, COSV64057430; called by muse, mutect2, varscan2
- KIAA1755 | c.546C>T p.T182= | Silent (SNP) | VAF 53/529 reads (10%) | catalogued as rs377651743; called by muse, mutect2, varscan2
- LTBP4 | c.1470G>A p.Q490= (on ENST00000308370 / NM_001042544.1; = p.Q453= on NM_003573.2) | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as rs1450011707, COSV52583136; called by muse, mutect2
- MED15 | c.1914G>A p.L638= (on ENST00000263205 / NM_001003891.3; = p.L598= on NM_015889.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs777175728, COSV99488299; called by muse, mutect2, varscan2
- MUC16 | c.9786G>T p.L3262= | Silent (SNP) | VAF 150/724 reads (21%) | catalogued as rs759864212, COSV67463057; called by muse, mutect2, varscan2
- MYO15A | c.6387A>T p.A2129= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV52756021; called by muse, mutect2, varscan2
- MYO15A | c.9366A>C p.T3122= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV52756030; called by muse, mutect2, varscan2
- NBEA | c.5205T>C p.I1735= | Silent (SNP) | VAF 44/123 reads (36%) | catalogued as rs758849055, COSV59780946; called by muse, mutect2, varscan2
- PER1 | c.2136G>T p.A712= | Silent (SNP) | VAF 150/191 reads (79%) | catalogued as COSV57919302; called by muse, mutect2, varscan2
- PPARGC1B | c.360C>T p.D120= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs576291052, COSV58528931; called by mutect2, varscan2
- RBM15 | c.1293A>G p.K431= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV63923443; called by muse, mutect2, varscan2
- RBM39 | c.738T>C p.S246= | Silent (SNP) | VAF 26/128 reads (20%) | catalogued as COSV53615107; called by muse, mutect2, varscan2
- RYR2 | c.2127G>A p.G709= | Silent (SNP) | VAF 12/154 reads (8%) | catalogued as rs1391671861, COSV100773212; called by muse, mutect2
- SELE | c.252A>T p.V84= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV60975176; called by mutect2, varscan2
- SLC7A10 | c.1050G>T p.L350= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV99472629; called by muse, mutect2
- SLC8A2 | c.2190G>A p.T730= | Silent (SNP) | VAF 27/133 reads (20%) | catalogued as COSV52639554; called by muse, varscan2
- TCHH | c.1641G>A p.E547= | Silent (SNP) | VAF 42/268 reads (16%) | catalogued as rs374409875, COSV64273428; called by muse, mutect2, varscan2
- TFAP2D | c.201C>G p.T67= | Silent (SNP) | VAF 173/740 reads (23%) | catalogued as COSV99148243; called by muse, mutect2, varscan2
- TMEM217 | c.210C>T p.F70= | Silent (SNP) | VAF 36/1258 reads (3%) | catalogued as rs1459859055, COSV100362721; called by muse, mutect2
- UBA1 | c.1767C>G p.V589= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV60112533; called by muse, mutect2, varscan2
- UGT1A4 | c.120C>G p.P40= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as COSV59388307; called by muse, mutect2, varscan2
- ZFP37 | c.1092C>T p.L364= | Silent (SNP) | VAF 54/567 reads (10%) | catalogued as COSV100953365; called by muse, mutect2
- DENND10P1 | n.660G>T | RNA (SNP) | VAF 27/260 reads (10%) | called by muse, mutect2, varscan2
- FAM74A3 | n.377C>A | RNA (SNP) | VAF 47/291 reads (16%) | catalogued as rs1229761466; called by muse, mutect2, varscan2
